Gene-level copy-number profile of tumor specimen C3N-02631-02 from CPTAC case C3N-02631, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 77.0 years (28,135 days).
Specimen C3N-02631-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1668491-87c1-4468-9ae3-2993578caedf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02631-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/42e0425d-c5f3-4381-8f46-c048263effc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 18,371; copy number 2: 32,491; copy number 3: 6,128; copy number 4: 886; copy number 5: 400; copy number 6: 34; copy number 7: 14.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr9:10,532,145–10,532,411, 1 gene (within-gene range 0–1): AL135790.2.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr15:95,326,528–95,507,865, 2 genes (within-gene range 0–1): LINC00924, AC027013.1.
- chr15:101,887,354–101,979,093, 11 genes: WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:74,367,462–74,441,937, 5 genes (within-gene range 0–1): AC009053.2, NPIPB15, AC009053.4, CLEC18B, AC009053.3.
- chr17:15,699,577–16,045,015, 21 genes (within-gene range 0–1): ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2.
- chr17:16,040,472–16,044,961, 2 genes (within-gene range 0–1): AC002553.1, RPLP1P11.
- chr21:9,082,601–9,083,101, 1 gene (within-gene range 0–1): SOWAHCP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 448 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,212,982–156,456,763, 14 genes, copy number 5: PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1.
- chr1:179,730,191–181,238,604, 35 genes, copy number 5: AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732, AL358393.1, LINC01699.
- chr1:203,954,640–206,204,414, 75 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:209,827,972–211,492,162, 27 genes, copy number 5–6: UTP25, SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3, TRAF5, LINC00467, SNX25P1, ARPC3P2, RD3.
- chr3:188,941,715–190,892,429, 23 genes, copy number 5: TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC.
- chr3:197,445,061–197,888,436, 18 genes, copy number 6: AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1.
- chr5:602,620–15,939,795, 245 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr16:33,976,039–33,991,551, 2 genes, copy number 7 (within-gene range 2–7): AC133561.1, BCAP31P1.
- chr16:69,762,328–69,941,741, 1 gene, copy number 6 (within-gene range 4–6): WWP2.
- chr16:69,933,081–70,079,624, 8 genes, copy number 6: MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1.

Autosomal genes at a single copy (total copy number 1): 18,360. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
